Somatic mutation profile of tumor specimen TCGA-2G-AALN-01A (aliquot TCGA-2G-AALN-01A-11D-A42Y-10) from TCGA case TCGA-2G-AALN, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efdcc400-f837-4e18-8424-7a5b37d511e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AALN-10A (Blood Derived Normal), aliquot TCGA-2G-AALN-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19a34d2e-0caf-4e67-850f-133f420dcd32

The open-access MAF lists 16 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Intron 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD17 | c.5339A>G p.E1780G | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1359393345; called by muse, mutect2, varscan2
- CBWD1 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1364397343; called by muse, mutect2, varscan2
- GDF10 | c.430C>G p.R144G | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- HPR | c.1016A>G p.H339R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARK2 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC34A3 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- ZNF74 | c.404A>T p.Q135L | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALDOA | c.933G>A p.L311= (on ENST00000642816 / NM_001243177.4; = p.L257= on NM_184041.5) | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- CHST5 | c.708G>A p.A236= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- MARS1 | c.429A>G p.L143= | Silent (SNP) | VAF 41/221 reads (19%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.5853G>A p.Q1951= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV101100082; called by muse, mutect2, varscan2
- RPN1 | c.1290C>T p.F430= | Silent (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- SART1 | c.1080G>A p.L360= | Silent (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 6/48 reads (13%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- DMAC2L | chr14:50332217 del CT | 3'Flank (DEL) | VAF 19/81 reads (23%) | catalogued as rs758480039; called by pindel, varscan2
- TUBA4A | c.4-589C>T | Intron (SNP) | VAF 29/147 reads (20%) | catalogued as COSV50281400; called by muse, mutect2, varscan2
